CCDI case PBBNFX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2e435299-f66f-4e0c-8e0f-a8ae7c611cc9

Demographics
Sex at birth: female; Race: white.

Biospecimens (2 samples)
- Sample 0DDEQG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DDERH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
